Somatic mutation profile of cancer-model specimen HCM-BROD-0010-C25-85A (3D Organoid, passage 11; aliquot HCM-BROD-0010-C25-85A-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0010-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G3; Age at diagnosis: 53.9 years (19,673 days).
Specimen HCM-BROD-0010-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d828d89-1824-4722-820c-c3604e85fcb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0010-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0010-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8020c549-6535-4f30-bca0-639dc6341276

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Intron 3, Nonsense Mutation 3, RNA 1, Frame Shift Del 1, 5'UTR 1, Translation Start Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 110/260 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 176/179 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMER2 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 188/581 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs770891345; called by muse, mutect2, varscan2
- ARHGAP21 | c.3623T>C p.I1208T | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs367814916; called by muse, mutect2, varscan2
- AVPR2 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 230/667 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782753911, COSV100509377; called by muse, mutect2, varscan2
- C8orf48 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 56/59 reads (95%) | catalogued as rs766448217; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FIGN | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 94/349 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV60769256; called by muse, mutect2, varscan2
- GPR176 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs373118560; called by muse, mutect2, varscan2
- GYS2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs373682083; called by muse, mutect2, varscan2
- ITFG2 | c.405C>T p.I135= | Splice Region (SNP) | VAF 122/255 reads (48%) | catalogued as rs374998892; called by muse, mutect2, varscan2
- LIMK1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs370710652, COSV100283349; called by muse, mutect2, varscan2
- MNDA | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV63740672; called by muse, mutect2, varscan2
- RBFOX1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776698363, COSV60952220; called by muse, mutect2
- SCARF1 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 144/274 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs369633804; called by muse, mutect2, varscan2
- SGIP1 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 181/346 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99390485; called by muse, mutect2, varscan2
- SNTG1 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 67/286 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs867068094, COSV52461875, COSV99385396; called by muse, mutect2, varscan2
- SPTA1 | c.6730C>A p.Q2244K | Missense Mutation (SNP) | VAF 136/199 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934287; called by muse, mutect2, varscan2
- UHRF1BP1L | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | catalogued as rs1376524072, COSV99691528; called by muse, mutect2, varscan2
- VSX2 | c.350C>G p.T117S | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs763918029; called by muse, mutect2
- WIPI2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1198250582; called by muse, mutect2
- ZNF749 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs373133672; called by muse, mutect2, varscan2
- ZNF787 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1372299933; called by muse, mutect2, varscan2
- CD1C | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM193A | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- FCHSD1 | c.1927C>G p.P643A | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ME1 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NELFCD | c.1093T>A p.Y365N (on ENST00000602795; = p.Y347N on NM_198976.4) | Missense Mutation (SNP) | VAF 97/351 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NFE2L3 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NIPBL | c.7560T>G p.N2520K | Missense Mutation (SNP) | VAF 97/366 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NUDT9 | c.1020_1021del p.S340Rfs*4 | Frame Shift Del (DEL) | VAF 33/183 reads (18%) | called by mutect2, pindel, varscan2
- OTOG | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 382/384 reads (99%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OTUD4 | c.1505G>A p.G502E (on ENST00000447906 / NM_001366057.1; = p.G437E on NM_001102653.1) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, varscan2
- PCDHGB3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLCO1A2 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- SRRM4 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRERF1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 138/445 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.83440G>C p.G27814R (on ENST00000591111; = p.G20390R on NM_003319.4) | Missense Mutation (SNP) | VAF 36/321 reads (11%) | PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VILL | c.878T>G p.I293S | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB22 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 115/377 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF280B | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 255/399 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL6A5 | c.5559C>T p.N1853= (on ENST00000312481; = p.N1849= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/345 reads (32%) | catalogued as rs1434690072; called by muse, mutect2, varscan2
- CPNE9 | c.153G>T p.R51= | Silent (SNP) | VAF 135/454 reads (30%) | called by muse, mutect2, varscan2
- DNM1L | c.108C>T p.S36= | Silent (SNP) | VAF 99/218 reads (45%) | catalogued as rs182756299; ClinVar: likely benign; called by muse, mutect2, varscan2
- MKLN1 | c.405A>G p.P135= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as rs761391733; called by muse, mutect2, varscan2
- MORC4 | c.2412G>A p.Q804= | Silent (SNP) | VAF 69/307 reads (22%) | called by muse, mutect2, varscan2
- OBSCN | c.11832G>A p.A3944= | Silent (SNP) | VAF 38/547 reads (7%) | catalogued as rs3795794; called by muse, mutect2
- PLXDC2 | c.1353C>A p.T451= | Silent (SNP) | VAF 89/246 reads (36%) | called by muse, mutect2, varscan2
- POTEB3 | c.864G>T p.V288= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- TCERG1L | c.1200C>T p.S400= | Silent (SNP) | VAF 102/235 reads (43%) | catalogued as rs757435830; called by muse, mutect2, varscan2
- UNC80 | c.7716C>T p.D2572= | Silent (SNP) | VAF 144/304 reads (47%) | called by muse, mutect2, varscan2
- UVRAG | c.442C>A p.R148= | Silent (SNP) | VAF 47/270 reads (17%) | called by muse, mutect2, varscan2
- COL20A1 | c.3295-77G>T | Intron (SNP) | VAF 102/174 reads (59%) | called by muse, mutect2, varscan2
- EPS15 | c.1041-87A>C | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.268C>T | RNA (SNP) | VAF 18/137 reads (13%) | catalogued as rs765100841; called by muse, mutect2, varscan2
- JAZF1 | c.116-60G>A | Intron (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- SLC6A18 | c.-10C>T | 5'UTR (SNP) | VAF 76/322 reads (24%) | called by muse, mutect2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 18/156 reads (12%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
